Gene-level copy-number profile of tumor specimen ALCH-B3FD-TTP1-A from ALCHEMIST case ALCH-B3FD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.1 years (27,047 days).
Specimen ALCH-B3FD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 26d76354-1b33-4be2-8f23-b2eed6a882a9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3FD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/91c9dab1-2f48-4868-83bb-a76d9f4969f7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 1,860; copy number 2: 16,601; copy number 3: 20,203; copy number 4: 14,682; copy number 5: 2,499; copy number 6: 1,463; copy number 7: 806; copy number 8: 86; copy number 9: 1; copy number 10: 40; copy number 11: 61; copy number 12: 56.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:155,247,205–155,255,483, 1 gene: FAM189B.
- chr2:241,010,045–241,010,744, 1 gene (within-gene range 0–3): AC093585.1.
- chr4:8,846,076–8,871,839, 2 genes: HMX1, AC116612.1.
- chr6:158,764,661–158,819,368, 2 genes (within-gene range 0–2): MIR3918, EZR.
- chr8:27,633,868–27,676,776, 1 gene: SCARA3.
- chr9:61,581,813–61,666,386, 5 genes: AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr9:136,494,433–136,549,893, 5 genes: NOTCH1, MIR4673, AL592301.1, MIR4674, NALT1.
- chr10:109,528,119–109,534,990, 2 genes: PHB2P1, BTF3P15.
- chr10:133,230,217–133,241,928, 2 genes: UTF1, VENTX.
- chr10:133,344,643–133,350,726, 2 genes (within-gene range 0–1): BANF1P2, AL360181.1.
- chr10:133,355,158–133,358,025, 1 gene: FUOM.
- chr11:45,885,651–45,907,272, 3 genes: MAPK8IP1, AC068385.1, C11orf94.
- chr12:124,529,722–124,542,873, 3 genes (within-gene range 0–3): AC073592.7, AC073592.3, AC073592.9.
- chr16:89,159,146–89,169,147, 2 genes: LINC00304, LINC02138.
- chr19:4,007,736–4,066,899, 3 genes: PIAS4, ZBTB7A, AC016586.1.
- chr22:50,263,713–50,327,012, 5 genes: MAPK11, PLXNB2, DENND6B, CR559946.1, CR559946.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,050 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,490,832–15,683,128, 12 genes, copy number 7 (within-gene range 5–7): CASP9, DNAJC16, SCARNA21B, AL121992.3, AGMAT, AL121992.1, CHCHD2P6, RNU7-179P, CD24P1, DDI2, RSC1A1, AL121992.2.
- chr1:18,839,599–19,329,300, 16 genes, copy number 7: TAS1R2, ALDH4A1, MIR4695, MIR1290, IFFO2, AL137127.1, UBR4, EMC1-AS1, EMC1, MRTO4, AKR7L, AKR7A3, AL035413.1, AKR7A2, RNU6-1099P, SLC66A1.
- chr1:20,290,919–23,424,748, 93 genes, copy number 7 (broad region; genes not listed).
- chr1:24,415,802–30,037,612, 204 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr1:30,409,560–33,512,743, 111 genes, copy number 7 (broad region; genes not listed).
- chr6:35,832,966–35,921,342, 1 gene, copy number 7 (within-gene range 4–7): SRPK1.
- chr7:1,570,073–7,293,880, 133 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr8:76,681,239–81,112,068, 60 genes, copy number 7 (within-gene range 3–7): ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1, AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605, AC138646.1, AC100870.1, RPL3P9, STMN2, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, PAG1, AC022778.1, AC079209.2.
- chr8:84,162,118–86,818,558, 56 genes, copy number 7–10: TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1, REXO1L8P, REXO1L3P, REXO1L1P, REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, MIOXP1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1.
- chr19:12,763,003–13,158,788, 41 genes, copy number 8 (within-gene range 4–8): HOOK2, AC018761.3, MIR5684, JUNB, PRDX2, AC018761.2, THSD8, RNASEH2A, RTBDN, AC020934.1, MAST1, MIR6794, DNASE2, AC020934.2, KLF1, GCDH, RPS6P25, SYCE2, MIR5695, FARSA, FARSA-AS1, CALR, MIR6515, AC092069.1, RAD23A, GADD45GIP1, DAND5, NFIX, AC138474.1, AC007787.1, AC007787.2, LYL1, TRMT1, NACC1, AC005546.1, AC011446.1, STX10, IER2, AC011446.3, AC011446.2, RPL12P42.
- chr19:16,549,831–16,572,415, 1 gene, copy number 7 (within-gene range 5–7): SLC35E1.
- chr19:16,565,551–17,219,829, 31 genes, copy number 7 (within-gene range 5–7): AC008764.5, AC008764.8, MED26, AC008764.4, AC008764.7, AC008764.9, AC008764.10, AC008764.2, AC024075.3, SMIM7, AC024075.2, AC024075.1, TMEM38A, AC008737.2, NWD1, AC008737.3, SIN3B, AC008737.1, F2RL3, CPAMD8, RN7SL835P, RN7SL823P, AC020908.2, HAUS8, AC020908.1, MYO9B, AC020908.3, AC020913.1, AC020913.3, AC020913.2, USE1.
- chr19:17,435,509–17,460,926, 4 genes, copy number 10: TMEM221, AC010319.2, AC010319.5, NXNL1.
- chr19:19,063,994–19,508,931, 18 genes, copy number 10: SLC25A42, TMEM161A, MEF2B, BORCS8-MEF2B, BORCS8, RFXANK, NR2C2AP, NCAN, RNU6-1028P, AC138430.1, HAPLN4, AC138430.2, TM6SF2, SUGP1, MAU2, GATAD2A, AC092067.1, MIR640.
- chr19:19,668,796–21,852,125, 107 genes, copy number 7–11 (broad region; genes not listed).
- chr19:27,793,431–27,984,984, 9 genes, copy number 12 (within-gene range 4–12): AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1.
- chr19:29,489,775–30,016,612, 12 genes, copy number 7 (within-gene range 3–7): AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32.
- chr19:32,345,594–32,485,895, 3 genes, copy number 10: ZNF507, AC007773.1, DPY19L3.
- chr19:34,172,504–35,384,052, 69 genes, copy number 8–12 (broad region; genes not listed).
- chr19:36,379,351–37,248,738, 34 genes, copy number 7: AC092296.4, ZFP82, AC092296.3, ZNF566, AC092295.2, CTBP2P7, ZNF260, AC092295.1, ZNF529, ZNF529-AS1, ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1, ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568, ZNF420, AC010632.3, AC010632.1, AC010632.2, AC012309.1, ZNF585A, AC012309.2, ZNF585B, ZNF383.
- chr19:38,878,555–39,409,678, 32 genes, copy number 8: SIRT2, NFKBIB, CCER2, SARS2, AC011455.2, MRPS12, ERVK9-11, FBXO17, AC011455.8, FBXO27, AC010605.1, ACP7, PAK4, AC011443.1, NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530.
- chr22:18,906,238–18,947,732, 2 genes, copy number 10 (within-gene range 2–10): AC007326.4, PRODH.
- chr22:21,370,064–21,371,945, 1 gene, copy number 8: AP000552.1.

Autosomal genes at a single copy (total copy number 1): 1,860. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
